TCGA case TCGA-UD-AABZ — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Western Australia. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97408569-ef36-46d6-941a-aca9e0ab297e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 46 years; Vital status: Dead; Days to death: 197 days.

Diagnoses (1)
1. Epithelioid mesothelioma, malignant: ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 46.3 years (16,913 days); Year of diagnosis: 2004; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 197 days.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Antineoplastic Vaccine; Days to treatment start: 42 days; Days to treatment end: 56 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed Disodium; Days to treatment start: 103 days; Days to treatment end: 168 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 162 days; Days to treatment end: 162 days; Treatment dose: 8 Gy; Number of fractions: 1; Treatment anatomic sites: Regional Site.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.

Follow-up (2 entries)
- Days to follow up: 197 days; Disease response: With Tumor.
- ECOG performance status: 2; Timepoint: Other.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Mesothelin 5.17 nmol/L [Blood test normal range lower: 0.3; Blood test normal range upper: 2.5].
- Creatinine 0.837 mg/dL [Blood test normal range lower: 0.679; Blood test normal range upper: 1.188].

Exposures
- Occupation type: Information and Communications Technology Operations and User Support Technicians.
- Exposure type: Asbestos; Age at onset: 27; Exposure source: Secondary.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UD-AABZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-UD-AABZ-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UD-AABZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UD-AABZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Information services.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Serum mesothelin prior treatment: 5.169.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Performance status other timing: Post surgery and vaccine.
- Drug treatment 1: Clinical trial drug classification: Vaccine; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Alimta.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 197 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 197 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 197 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UD-AABZ-01A-12D-A39Q-01): tumor purity 0.67, ploidy 1.8, whole-genome doublings 0.
